Surgical pathology report (de-identified scan), TCGA case TCGA-23-2072, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2072-01A (Primary Tumor).

[page 1 of 3]
SURGICAL

PATH #

A/S:

Rec:

Col:

Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

TCGA-23-2072

=====

DIAGNOSIS:

1. OMENTUM, BIOPSY:
- Infiltrating serous papillary adenocarcinoma
- High grade
2. RIGHT TUBE AND OVARY:
- Serous papillary adenocarcinoma, ovary
- High grade
- Psammoma bodies
- Unremarkable fallopian tube
3. LEFT TUBE AND OVARY:
- Serous papillary adenocarcinoma, ovary
- High grade
- Tumor invades fallopian tube from serosa up to the outer portions of mucosa
- Psammoma bodies
4. UTERUS AND CERVIX:
- Serous papillary adenocarcinoma invading uterine wall serosa and outer portions of myometrium
- Psammoma bodies
- Adenomyomatous polyp, endometrial/endocervical polyp
- Leiomyoma, subserosal, minute
- Benign endocervical mucosa with focal squamous metaplasia, nabothian cyst and mild chronic non-specific inflammation
5. PELVIC MASS:
- Serous papillary adenocarcinoma
- High grade
6. SIGMOID MASS:
- Serous papillary adenocarcinoma
- High grade
7. ANTERIOR LIVER TUMOR:
- Serous papillary adenocarcinoma, metastatic
8. POSTERIOR LIVER TUMOR:
- Serous papillary adenocarcinoma, metastatic
9. RIGHT RETROPERITONEAL TUMOR:
- Serous papillary adenocarcinoma
10. OMENTUM TUMOR:
- Serous papillary adenocarcinoma
- Psammoma bodies

[page 2 of 3]
11. ABDOMINAL TUMOR:

- Serous papillary adenocarcinoma, metastatic
- Psammoma bodies

=====

HISTORY: Pelvic mass; ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: OMENTUM

Labeled "omentum" and received in formalin is a 5.5 x 3.5 x 2.5 cm firm, yellow, nodular adipose tissue with red-brown discoloration. Cut surface is yellow-tan, firm and remarkable for two white circular nodules measuring 0.6 and 0.5 cm in diameter.

A. Representative sections - 3

2: RIGHT TUBE AND OVARY

Labeled "right tube and ovary" and received in formalin is a 7.0 cm in length, 0.5 cm in diameter segment of fallopian tube with fimbriated end. The serosa is pink-tan and focally hyperemic. Cut surface reveals a 0.1 cm wall with a patent pinpoint lumen. Attached is a 3.5 x 2.0 x 2.0 cm ovary with a pink-tan, focally hyperemic, firm, nodular cortical surface. The cut surface is remarkable for pink-tan, friable tissue; a 1.7 x 1.0 x 1.0 cm subcortical, smooth-walled cyst; a 2.0 x 1.0 x 0.6 cm firm, white, homogeneous nodule and a scant amount of normal variegated, pink-tan ovarian parenchyma with two corpora albicantia. The mesovarium is markedly hemorrhagic. Representative sections submitted.

- B. Cross section of ovary including friable tissue, firm white tissue, cyst, normal ovarian parenchyma with corpus albicans - 1
- C. Cross section of ovary with fallopian tube - 2

3: LEFT TUBE AND OVARY

Labeled "left tube and ovary" and received in formalin is a 60 gram, 7.0 x 5.0 x 4.5 cm ovary with a pink-tan distended cortical surface with numerous (greater than ten) pink-tan, friable tumor studs ranging from 0.5 x 0.3 x 0.3 cm up to 3.0 x 2.8 x 2.0 cm. The cut surface is remarkable for both solid and cystic areas. The largest cyst measures 4.0 x 4.0 x 4.0 cm and is remarkable for 30 cc of amber serous fluid and multiple yellow-pink papillary excrescences extending from the inner lining of the cyst wall. Attached is a 3.0 cm in length, 0.4 cm in average diameter segment of fallopian tube with pink-tan focally hyperemic serosa. Fimbriated end is present. Cut surface reveals a 0.1 cm wall with patent pinpoint lumen. Also present is a moderate amount of pink-tan, moderately hemorrhagic mesovarium tissue. Representative sections submitted.

- D. Cross section of cystic and solid area of tumor, fallopian tube - 2
- E. Cross section of cystic and solid tumor and fallopian tube - 3

4: UTERUS AND CERVIX

Labeled "uterus and cervix" and received in formalin is a 75 gram symmetric uterus with cervix and without bilateral adnexa, measuring 4.0 cm cornu to cornu, 7.0 cm superior to inferior and 4.0 cm anterior to posterior. The serosa is pink-tan and focally disrupted by a 4.0 x 3.0 cm area of hemorrhage on the anterior surface, multiple cysts ranging from 0.2 up to 0.7 cm in diameter and patchy areas of grey-tan fibrinous exudate. There is a 0.5 x 0.5 x 0.4 cm tan-white subserosal spherical nodule on the posterior corpus which on cut section has a tan-white, homogeneous, whorled surface without hemorrhage, calcification or necrosis. The cervix measures 3.3 x 2.8 cm in area with a 0.7 cm in width anterior vaginal cuff and 1.5 cm in width posterior vaginal cuff. The ectocervical mucosa is

[page 3 of 3]
tan-pink and moderately hyperemic. The os measures 1.5 x 1.0 cm, is round and has a pink-tan, firm, nodular polyp extending 2.0 cm from the opening. The specimen is bivalved to reveal a 2.5 cm in length, 1.0 cm in width endocervical canal with a tan-pink, smooth mucosa. The endometrial cavity measures 3.7 cm in length, 1.7 cm in width. The endometrial lining measures 0.1 cm in thickness and is tan-pink and lush. The lining is significant for a 6.5 x 2.2 x 1.5 cm polyp which extends from the anterior lower uterine segment through the endocervical canal with multiple foci of adhesions and then continues out through the cervical os, extending 2.0 cm from the opening. Also present is a 0.5 x 0.2 x 0.2 cm white endometrial polyp extending from the posterior lower uterine segment. The myometrium measures 1.6 cm in maximum thickness and is tan-pink. No lesions are grossly identified. Representative sections submitted.

F. Anterior ectocervix - 1

G. Anterior lower uterine segment including base of large polyp and area of disruption on serosa of hemorrhage and fibrinous adhesions - 1

H. Continuation of large polyp -

I. Full thickness myometrium of anterior corpus - 1

J. Posterior ectocervix and vaginal cuff - 1

K. Posterior lower uterine segment with small polyp - 1

L. Full thickness myometrium, posterior corpus - 1

M. Subserosal nodule - 1

N. Cross section of serosa at anterior corpus in area of hemorrhage and fibrous adhesions - 1

5: PELVIC MASS

Labeled "pelvic mass" and received in formalin is a 1.0 x 0.7 x 0.7 cm pink-tan, friable, papillary fragment of tissue with foci of hemorrhage and yellow fibrinous adhesions.

O. All embedded - 1

6: SIGMOID MASS

Labeled "sigmoid mass", received fresh in the Operating Room for intraoperative frozen section diagnosis and subsequently fixed in formalin, are two soft, pink-tan 2.0 x 1.1 x 0.3 cm and 1.0 x 1.5 x 0.9 cm fragments of tissue. Representative sections submitted.

P. Frozen section remnant -

Q. Cross sections of fragments - 2

7: ANTERIOR LIVER TUMOR

Labeled "anterior liver tumor" and received in formalin is a 7.0 x 7.0 x 4.0 cm tan-pink, focally hemorrhagic, friable aggregate of papillary tissue and blood clot.

R. Representative sections - 2

8: POSTERIOR LIVER TUMOR

Labeled "posterior liver tumor" and received in formalin is a 4.0 x 3.0 x 2.5 cm aggregate of pink-tan friable papillary tissue.

S. Representative sections - 2

9: RIGHT RETROPERITONEAL TUMOR

Labeled "right peritoneal tumor" and received in formalin is a 7.0 x 6.0 x 2.5 cm aggregate of tan-pink friable papillary tissue fragments and blood clot.

T. Representative sections - 2

10: OMENTUM TUMOR

Labeled "omentum tumor" and received in formalin is an 8.0 x 5.0 x 3.5 cm aggregate of pink-tan friable nodular adipose tissue with red-brown discoloration and adherent blood clot. Cross section reveals a 5.0 x 2.5 x 2.0 cm yellow-white, firm nodular mass surrounded by the

Source: NCI Genomic Data Commons file 5142c767-1f50-48a8-9709-c78928e1de22 (TCGA-23-2072.B0475CC1-EDD5-451C-8F26-EC3594811F2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).